Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A411, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A411-01A (Primary Tumor).

Path Report:CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 2 x 1.5 x 1 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: 0/13 positive for metastasis (Regional 0/13)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O3

carcinoma, squamous cell, NOS
8070/3

Site: Cervix, NOS
C53.9

7.20.12
EP

Reviewed: [Signature]	Date Reviewed: 7/20/12	

Source: NCI Genomic Data Commons file ea805cd2-8882-469c-9410-9271718e6988 (TCGA-EA-A411.A7CCC7A3-CF3C-4722-B1F5-890B3A4D9A6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).